Gene-level copy-number profile of tumor specimen ALCH-ADNJ-TTP1-A from ALCHEMIST case ALCH-ADNJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 56.8 years (20,756 days).
Specimen ALCH-ADNJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31a6c515-775f-428b-aa71-625dee8ac6ef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADNJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/806f4e49-66b6-4c55-a68c-9254bdf9dfbc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 5,376; copy number 2: 48,621; copy number 3: 4,303; copy number 4: 28; copy number 5: 44; copy number 6: 9; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,569,152–50,596,168, 1 gene (within-gene range 0–3): HEMK1.
- chr4:8,959,628–8,982,360, 2 genes: UNC93B8, AC073648.3.
- chr9:136,673,143–136,687,457, 1 gene: AGPAT2.
- chr13:112,052,078–112,052,138, 1 gene: AL138691.1.
- chr13:112,067,149–112,071,706, 1 gene: SOX1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,977,153–144,097,525, 11 genes, copy number 5 (within-gene range 2–5): PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1.
- chr9:137,299,631–137,302,271, 1 gene, copy number 7: NRARP.
- chr9:137,434,364–137,441,816, 1 gene, copy number 7 (within-gene range 3–7): ENTPD8.
- chr14:22,871,740–23,352,912, 33 genes, copy number 5: LRP10, REM2, RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707, AJUBA, AL132780.2, C14orf93, AL132780.5, PSMB5, AL132780.4, PSMB11, CDH24, ACIN1, C14orf119, LMLN2, CEBPE, SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17.
- chr14:35,121,846–35,317,493, 9 genes, copy number 6 (within-gene range 3–6): PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6.

Autosomal genes at a single copy (total copy number 1): 5,376. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
